Somatic mutation profile of tumor specimen 0DNKZJ from CCDI case PBCBUW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 0.7 years (252 days).
Specimen 0DNKZJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4fce051-7f44-4ec8-9f5f-eba3404ed8b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNKZE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deb2bb40-2c5c-43b8-b571-3c60f87f1b4e

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTM1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 337/889 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); catalogued as COSV60334103; called by muse, mutect2, varscan2
- SUPT16H | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 248/625 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- EXOC3L1 | c.996G>A p.A332= | Silent (SNP) | VAF 152/458 reads (33%) | catalogued as rs199918872, COSV52045642; called by muse, mutect2, varscan2
- RNF213 | c.10161C>T p.S3387= | Silent (SNP) | VAF 204/572 reads (36%) | catalogued as rs764716167, COSV60396277; called by muse, mutect2, varscan2
